Somatic mutation profile of tumor specimen TARGET-30-PARNTS-01A (aliquot TARGET-30-PARNTS-01A-01D) from TARGET case TARGET-30-PARNTS, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.8 years (1,035 days).
Specimen TARGET-30-PARNTS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 233cb66d-c48b-46c7-ac52-9a9f2a3e20da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARNTS-10A (Blood Derived Normal), aliquot TARGET-30-PARNTS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/509ce2c9-61ab-4cc6-810a-582d0a415909

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIR2DL1 | c.803G>A p.C268Y | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1167540699; called by muse, mutect2, varscan2
- NRL | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV53744922; called by muse, mutect2, varscan2
- PKLR | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as rs756549612, COSV100712944, COSV61361651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEPTIN3 | c.439A>C p.N147H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV52172898; called by muse, mutect2, varscan2
- TMEM67 | c.2015T>C p.F672S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60041233; called by muse, mutect2, varscan2
- TTLL8 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs374245397; called by muse, mutect2, varscan2
- COLGALT2 | c.1037T>C p.M346T | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2
- GRK7 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2
- ABCD1 | c.762G>A p.T254= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1557052528, COSV54385903; called by muse, varscan2
- HACE1 | c.792G>A p.Q264= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV53503959; called by muse, mutect2
- INTS8 | c.2211C>A p.G737= | Silent (SNP) | VAF 83/389 reads (21%) | catalogued as COSV58251476; called by muse, mutect2, varscan2
- LITAF | c.180G>A p.S60= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs1430973151, COSV59655907; called by muse, mutect2, varscan2
